Somatic mutation profile of tumor specimen TCGA-DX-AB36-01A (aliquot TCGA-DX-AB36-01A-11D-A417-09) from TCGA case TCGA-DX-AB36, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DX-AB36-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9e0a301-c44b-4f83-a9d3-8e619e319ed8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB36-10A (Blood Derived Normal), aliquot TCGA-DX-AB36-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03cc3c72-2ce1-45a6-b262-1aa3ef382ea1

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALKBH4 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99479081; called by muse, mutect2, varscan2
- AVIL | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 125/465 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV99142132; called by muse, mutect2
- BTN1A1 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778400918, COSV55067292; called by muse, mutect2, varscan2
- CATSPER1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100375466; called by muse, mutect2, varscan2
- CELSR1 | c.6685C>T p.R2229C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs139210959; called by muse, mutect2
- CSRNP3 | c.1504G>A p.V502I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.042); catalogued as rs1290011348, COSV58776393; called by muse, mutect2, varscan2
- ELP1 | c.526A>G p.R176G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV101010252; called by muse, mutect2, varscan2
- EYA4 | c.1140G>A p.W380* (on ENST00000531901 / NM_001301013.1; = p.W374* on NM_004100.5) | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100766433, COSV62062623; called by muse, mutect2
- FAM83G | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs760541119, COSV100524669; called by muse, mutect2, varscan2
- FRK | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as COSV101661716; called by muse, mutect2, varscan2
- MUC16 | c.38107C>G p.L12703V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.91); catalogued as COSV101197270; called by muse, mutect2, varscan2
- MYO1H | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 21/384 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as rs544703841, COSV100182899, COSV100183189; called by muse, mutect2
- OR4C46 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); catalogued as rs137991158, COSV100061123; called by muse, mutect2, varscan2
- PIK3CD | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100739859, COSV100740029; called by muse, mutect2
- RPF2 | c.773C>G p.T258S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.035); catalogued as COSV100923207, COSV64369468; called by muse, mutect2, varscan2
- RYR2 | c.8899G>A p.V2967I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs751546090, COSV100767002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHROOM2 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs757929241, COSV66608016; called by muse, mutect2, varscan2
- SLC35A5 | c.1060A>G p.R354G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV99656649; called by muse, mutect2, varscan2
- SYNE1 | c.9175C>T p.Q3059* (on ENST00000367255 / NM_182961.4; = p.Q3066* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99549015; called by muse, mutect2, varscan2
- TMTC3 | c.396A>G p.I132M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV99897875; called by muse, mutect2, varscan2
- AVIL | c.168C>T p.S56= | Silent (SNP) | VAF 108/380 reads (28%) | catalogued as rs1246456253, COSV99142133; called by muse, mutect2
- CHM | c.57T>G p.P19= | Silent (SNP) | VAF 63/74 reads (85%) | catalogued as COSV100718079; called by muse, mutect2, varscan2
- LTBP3 | c.222C>A p.T74= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100098719, COSV57240557, COSV57243636; called by muse, mutect2
- RYR1 | c.9861C>T p.R3287= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs375156852; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPR | c.453C>T p.T151= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs952303022, COSV99317968; called by muse, mutect2, varscan2
- TUFT1 | c.696G>A p.L232= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100776995; called by muse, mutect2
